Gene-level copy-number profile of tumor specimen ALCH-B27Y-TTP1-A from ALCHEMIST case ALCH-B27Y, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.7 years (21,066 days).
Specimen ALCH-B27Y-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a8896d2d-b9cc-466f-aa21-ff78a46e1ec0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B27Y-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,256 have no estimate.
https://portal.gdc.cancer.gov/files/dddee166-c601-4aea-9ab8-effa902ade69

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 1,292; copy number 2: 53,918; copy number 3: 3,082; copy number 4: 6; copy number 5: 14; copy number 6: 3; copy number 7: 5; copy number 9: 1; copy number 35: 1.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,359,809–90,367,699, 2 genes: AC233263.1, AC233263.7.
- chr2:241,849,884–241,873,823, 2 genes: PDCD1, RTP5.
- chr3:50,287,732–50,312,381, 4 genes (within-gene range 0–2): IFRD2, HYAL3, NAA80, HYAL1.
- chr4:2,463,797–2,464,124, 1 gene (within-gene range 0–2): AL645924.1.
- chr4:54,221,126–54,221,472, 1 gene (within-gene range 0–2): RPL22P13.
- chr8:142,763,116–142,812,120, 7 genes: AC083841.1, LYNX1-SLURP2, SLURP2, LYNX1, LY6D, AC083841.2, AC083841.4.
- chr10:133,070,929–133,131,675, 2 genes: ADGRA1, ADGRA1-AS1.
- chr10:133,160,219–133,226,412, 1 gene: KNDC1.
- chr11:1,223,066–1,262,172, 3 genes (within-gene range 0–2): MUC5B, MUC5B-AS1, MIR6744.
- chr11:1,469,457–1,501,247, 1 gene: MOB2.
- chr14:18,333,726–18,419,273, 4 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr15:25,172,635–25,172,716, 1 gene (within-gene range 0–2): SNORD115-2.
- chr16:921,033–934,495, 1 gene (within-gene range 0–2): LMF1-AS1.
- chr17:22,221,221–22,221,605, 1 gene: FTLP13.
- chr17:81,461,013–81,461,937, 1 gene (within-gene range 0–1): AC110285.4.
- chr17:81,976,807–82,017,406, 1 gene: ASPSCR1.
- chr17:82,031,678–82,037,709, 3 genes: RAC3, DCXR, AC137723.1.
- chr17:82,057,506–82,065,887, 1 gene: DUS1L.
- chr20:63,540,810–63,556,695, 3 genes: SRMS, AL121829.2, FNDC11.
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.
- chr21:10,612,455–13,016,692, 4 genes: SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 24 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:32,649,193–32,848,156, 17 genes, copy number 5–7: AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3, AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10, AC137761.1, AC137761.2, AC142086.2, IGHV2OR16-5.
- chr21:8,680,538–8,680,934, 1 gene, copy number 6: CR381572.2.
- chr21:43,159,066–43,162,277, 1 gene, copy number 9: AP001631.1.
- chr22:18,873,543–18,947,732, 5 genes, copy number 5–35 (within-gene range 2–35): FAM230F, AC008103.1, DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 1,292. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
